Somatic mutation profile of tumor specimen TCGA-BG-A0W2-01A (aliquot TCGA-BG-A0W2-01A-11D-A117-09) from TCGA case TCGA-BG-A0W2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 57.5 years (20,998 days).
Specimen TCGA-BG-A0W2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3edd34e-fe24-460b-8347-a1d4a69641b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0W2-10A (Blood Derived Normal), aliquot TCGA-BG-A0W2-10A-01X-A10H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2704494-bcb2-4251-aed3-3d0fd8588b88

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Splice Site 1, Splice Region 1, Frame Shift Del 1, 3'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 33/77 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 115/143 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD4 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202089812, COSV53529534; called by muse, mutect2, varscan2
- ACSM1 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs376792697; called by muse, mutect2, varscan2
- ADH1A | c.345C>T p.N115= | Splice Region (SNP) | VAF 94/230 reads (41%) | catalogued as rs1412779396, COSV52926005; called by muse, mutect2, varscan2
- AHCY | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); catalogued as rs573146559, COSV54153626, COSV99463946; called by muse, mutect2, varscan2
- APP | c.2020G>T p.E674* | Nonsense Mutation (SNP) | VAF 28/107 reads (26%) | catalogued as COSV61003844; called by muse, mutect2, varscan2
- ARHGAP36 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52271146; called by muse, mutect2, varscan2
- ARSH | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as rs777648295, COSV66963765; called by muse, mutect2, varscan2
- FAM110B | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1403944505, COSV64067599; called by muse, mutect2
- FBLN2 | c.1199C>A p.P400Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.133); catalogued as COSV55490006; called by muse, mutect2, varscan2
- GRIP1 | c.1939G>A p.E647K (on ENST00000359742 / NM_001379345.1; = p.E595K on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV54039062; called by muse, mutect2, varscan2
- KCNC1 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56397792; called by muse, mutect2, varscan2
- LRRTM4 | c.1731G>T p.R577S | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as COSV69175207; called by muse, mutect2, varscan2
- NDUFS8 | c.513T>G p.F171L | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV55837201; called by muse, mutect2, varscan2
- OGT | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV65482374; called by muse, mutect2, varscan2
- OR51Q1 | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 140/362 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56180306; called by muse, mutect2, varscan2
- OR5AC2 | c.326G>T p.S109I | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV62280064; called by muse, mutect2, varscan2
- PCDHB5 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as rs369354928, COSV50666176; called by muse, mutect2, varscan2
- PCDHGA7 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); catalogued as COSV53975828; called by muse, mutect2, varscan2
- PLD2 | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs116011301, COSV54005552; called by muse, mutect2, varscan2
- PPP2R5A | c.1226+1G>A p.X409_splice | Splice Site (SNP) | VAF 52/132 reads (39%) | catalogued as rs746097381, COSV54818925; called by muse, mutect2, varscan2
- SEPTIN12 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs764804787, COSV51616074, COSV51618840; called by muse, mutect2, varscan2
- USH2A | c.8423A>G p.E2808G | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56423624; called by muse, mutect2, varscan2
- CHD6 | c.1442dup p.N481Kfs*6 | Frame Shift Ins (INS) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- KMT2D | c.2172_2182del p.L725Tfs*2 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, varscan2
- AMPD1 | c.1335G>A p.A445= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs141829342; called by muse, mutect2, varscan2
- CEMIP2 | c.3414G>A p.R1138= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV65489156, COSV65489415; called by muse, mutect2, varscan2
- CHRNB3 | c.402C>T p.I134= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as rs768194990, COSV51493627; called by muse, mutect2, varscan2
- HOMER2 | c.210G>A p.T70= | Silent (SNP) | VAF 44/140 reads (31%) | catalogued as rs139619821, COSV58488227; called by muse, mutect2, varscan2
- KRT75 | c.1455C>T p.S485= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs749230989, COSV52875001; called by muse, mutect2
- LIMS2 | c.654C>T p.H218= (on ENST00000355119 / NM_001161403.3; = p.H242= on NM_017980.4) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs745965497, COSV55756836; called by muse, mutect2
- RLN3 | c.345G>C p.R115= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV54602787; called by muse, mutect2, varscan2
- TSC22D2 | c.2130A>G p.E710= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as COSV62623457; called by muse, mutect2, varscan2
- C16orf91 | c.*251G>A | 3'UTR (SNP) | VAF 52/119 reads (44%) | catalogued as COSV59950853; called by muse, mutect2, varscan2
